Somatic mutation profile of tumor specimen TCGA-29-1769-01A (aliquot TCGA-29-1769-01A-01W-0639-09) from TCGA case TCGA-29-1769, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 40.4 years (14,754 days).
Specimen TCGA-29-1769-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e2cd040-a90d-4af5-bfff-392d0a1eb864.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1769-10A (Blood Derived Normal), aliquot TCGA-29-1769-10A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef6d3169-62c6-49ca-b227-fc8af1662f37

The open-access MAF lists 85 somatic variants for this specimen: 66 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 17, Nonsense Mutation 4, Splice Site 2, Frame Shift Del 1, Intron 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.412_435del p.A138_L145del | In Frame Del (DEL) | VAF 34/58 reads (59%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ACACB | c.3779C>G p.P1260R | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV58128348, COSV58138022; called by muse, mutect2, varscan2
- AKAP7 | c.987C>G p.S329R (on ENST00000431975 / NM_016377.4; = p.S62R on NM_004842.4) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as rs755803517, COSV53835892; called by muse, mutect2, varscan2
- ARHGAP31 | c.3208G>A p.E1070K | Missense Mutation (SNP) | VAF 381/1050 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.202); catalogued as COSV51794915; called by muse, mutect2, varscan2
- ARRB2 | c.1007T>C p.V336A | Missense Mutation (SNP) | VAF 86/168 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV52617765; called by muse, mutect2, varscan2
- ASXL3 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as rs770800472, COSV52470277; called by muse, mutect2, varscan2
- B4GALNT2 | c.1609A>T p.T537S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1411881924, COSV55926852; called by muse, mutect2, varscan2
- CACNA1S | c.5079G>C p.E1693D | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.024); catalogued as COSV62940909; called by muse, mutect2, varscan2
- CD37 | c.120G>C p.K40N | Missense Mutation (SNP) | VAF 282/631 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100115024, COSV60544685; called by muse, mutect2, varscan2
- CENPS-CORT | c.109G>C p.D37H | Missense Mutation (SNP) | VAF 66/103 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV58364178; called by muse, mutect2, varscan2
- CLCA4 | c.2725G>C p.V909L | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV65283967; called by muse, mutect2, varscan2
- COBL | c.281T>G p.L94R | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.756); catalogued as COSV54360842, COSV99473924; called by muse, mutect2
- CUL1 | c.1369G>C p.E457Q | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV57389772; called by muse, mutect2, varscan2
- DNAH11 | c.2935A>G p.N979D | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60962507; called by muse, mutect2, varscan2
- EIF4G3 | c.1113C>G p.S371R | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV99945369; called by muse, mutect2
- ERC2 | c.2816A>C p.Q939P | Missense Mutation (SNP) | VAF 172/430 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV55633474; called by muse, mutect2, varscan2
- FAM120C | c.1561G>C p.D521H | Missense Mutation (SNP) | VAF 46/50 reads (92%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as COSV60260149; called by muse, mutect2, varscan2
- FBXO38 | c.767C>A p.T256K | Missense Mutation (SNP) | VAF 119/136 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57028929; called by muse, mutect2, varscan2
- FETUB | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 23/430 reads (5%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.996); catalogued as COSV99409127; called by muse, mutect2
- GOLGB1 | c.5222A>T p.K1741M | Missense Mutation (SNP) | VAF 140/706 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV61464354, COSV61467226; called by muse, mutect2, varscan2
- GPBP1L1 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV51970451; called by muse, mutect2, varscan2
- GPR155 | c.1751C>T p.T584I | Missense Mutation (SNP) | VAF 85/390 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV55039783; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.727G>T p.V243F | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99860994; called by muse, mutect2
- LEPR | c.2714C>G p.S905* | Nonsense Mutation (SNP) | VAF 97/226 reads (43%) | catalogued as COSV62749113; called by muse, mutect2, varscan2
- LOXL2 | c.1697G>T p.R566L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101207974, COSV101207996; called by muse, mutect2, varscan2
- MAP2 | c.1797A>C p.R599S | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.055); catalogued as COSV52296074; called by muse, mutect2, varscan2
- MEPCE | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52769425; called by muse, mutect2, varscan2
- NIBAN1 | c.1930G>T p.G644W | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100836574; called by muse, mutect2
- NLRP7 | c.2506A>G p.K836E (on ENST00000340844 / NM_206828.3; = p.K808E on NM_139176.3) | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.722); catalogued as COSV60176563; called by muse, mutect2, varscan2
- OGDH | c.1985G>A p.G662D | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56052351; called by muse, mutect2, varscan2
- OR5A1 | c.743T>G p.L248R | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100118460; called by muse, mutect2
- PAK2 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59080910, COSV59082297; called by muse, mutect2, varscan2
- PARP14 | c.874A>G p.K292E | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.084); catalogued as COSV71734923; called by muse, mutect2, varscan2
- PDE11A | c.743C>A p.A248D | Missense Mutation (SNP) | VAF 46/356 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.053); catalogued as COSV99614472; called by muse, mutect2
- PIGF | c.414G>A p.W138* | Nonsense Mutation (SNP) | VAF 14/28 reads (50%) | catalogued as COSV53231825; called by muse, mutect2
- PRB2 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 1382/1578 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs753828341, COSV66982746; called by mutect2, varscan2
- PROZ | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 217/238 reads (91%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as rs759057455, COSV61439134; called by muse, mutect2, varscan2
- PXDN | c.1043C>G p.P348R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53238214; called by muse, mutect2, varscan2
- RAD21 | c.595A>G p.T199A | Missense Mutation (SNP) | VAF 64/125 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV52060026, COSV52060488; called by muse, mutect2, varscan2
- RAP2A | c.175G>C p.A59P | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55355303; called by muse, mutect2, varscan2
- RELN | c.7807G>T p.G2603C | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59011588; called by muse, mutect2, varscan2
- ROMO1 | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV53615999; called by muse, mutect2, varscan2
- RPS3 | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV53704331; called by muse, mutect2, varscan2
- RYR2 | c.13386G>C p.L4462F | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.165); catalogued as COSV63692931; called by muse, mutect2, varscan2
- SCN8A | c.817T>C p.F273L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as rs796053234, COSV61984723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SETBP1 | c.4267A>T p.T1423S | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as COSV56326755; called by muse, mutect2, varscan2
- SHLD2 | c.950G>T p.C317F | Missense Mutation (SNP) | VAF 85/127 reads (67%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV53956279; called by muse, mutect2, varscan2
- SIDT1 | c.1734G>C p.M578I | Missense Mutation (SNP) | VAF 97/454 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV53502725, COSV53508883; called by muse, mutect2, varscan2
- SLC30A2 | c.623T>G p.V208G | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV65332901; called by muse, mutect2, varscan2
- SLC36A3 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 71/91 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as rs748603967, COSV58857253, COSV58858386; called by muse, mutect2, varscan2
- SLC7A2 | c.496G>T p.D166Y (on ENST00000494857 / NM_001370338.1; = p.D206Y on NM_003046.6) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs902671297, COSV50248074, COSV50257126; called by muse, mutect2, varscan2
- SORCS3 | c.639C>G p.I213M | Missense Mutation (SNP) | VAF 87/110 reads (79%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.474); catalogued as rs267602355, COSV63814340, COSV63824858; called by muse, mutect2, varscan2
- STOX1 | c.1611G>T p.L537F | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.669); catalogued as COSV53815733; called by muse, mutect2, varscan2
- SWI5 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV60792383; called by muse, mutect2, varscan2
- TCEA1 | c.83T>A p.L28Q | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67172771; called by muse, mutect2, varscan2
- TMEM131 | c.1990G>T p.A664S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as COSV51778788; called by muse, mutect2, varscan2
- TNRC6A | c.4405C>T p.Q1469* | Nonsense Mutation (SNP) | VAF 30/208 reads (14%) | catalogued as COSV59366634; called by muse, mutect2
- TPCN2 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as rs1315444087, COSV53730439; called by muse, mutect2
- TRPV2 | c.2024A>T p.Y675F | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as COSV58429028; called by muse, mutect2, varscan2
- TTC21B | c.659A>C p.K220T | Missense Mutation (SNP) | VAF 65/207 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as COSV54631967; called by muse, mutect2, varscan2
- UEVLD | c.522G>C p.W174C | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT tolerated (0.19); PolyPhen benign (0.221); catalogued as COSV55578731; called by muse, mutect2, varscan2
- UTP20 | c.3386C>A p.T1129N | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.138); catalogued as rs1355965089, COSV55379508; called by muse, mutect2, varscan2
- ZNF473 | c.463G>C p.G155R | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); catalogued as COSV54523931; called by muse, mutect2, varscan2
- IBTK | c.2730-5_2739del p.X910_splice | Splice Site (DEL) | VAF 14/17 reads (82%) | called by mutect2, varscan2
- ITSN2 | c.3547_3569del p.M1183Sfs*6 | Frame Shift Del (DEL) | VAF 43/140 reads (31%) | called by mutect2, pindel, varscan2
- PKD1L1 | c.6055-27_6056del p.X2019_splice | Splice Site (DEL) | VAF 16/58 reads (28%) | called by mutect2, varscan2
- ABL2 | c.3441G>A p.L1147= (on ENST00000502732 / NM_007314.4; = p.L1132= on NM_005158.5) | Silent (SNP) | VAF 73/161 reads (45%) | catalogued as rs1294481641, COSV61016588; called by muse, mutect2, varscan2
- CCR4 | c.231C>T p.Y77= | Silent (SNP) | VAF 11/133 reads (8%) | catalogued as COSV100447502; called by muse, mutect2
- CLCN1 | c.1344G>A p.V448= | Silent (SNP) | VAF 392/602 reads (65%) | catalogued as rs1358644372, COSV58371113; called by muse, varscan2
- FOXP4 | c.126G>C p.T42= | Silent (SNP) | VAF 38/54 reads (70%) | catalogued as COSV57220933; called by muse, mutect2, varscan2
- FRMPD3 | c.3708C>A p.G1236= | Silent (SNP) | VAF 53/61 reads (87%) | catalogued as COSV52192740; called by muse, mutect2, varscan2
- GPR83 | c.18G>A p.L6= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV54719222; called by muse, mutect2, varscan2
- HABP4 | c.582C>G p.G194= | Silent (SNP) | VAF 36/346 reads (10%) | catalogued as COSV64514955; called by muse, mutect2
- IGHV1OR15-9 | c.282C>T p.S94= | Silent (SNP) | VAF 144/197 reads (73%) | called by muse, mutect2, varscan2
- MTERF3 | c.1218A>G p.S406= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV54630211; called by muse, mutect2, varscan2
- NPAS2 | c.1797G>A p.L599= | Silent (SNP) | VAF 45/104 reads (43%) | catalogued as COSV59558977, COSV59562765; called by muse, mutect2, varscan2
- OR5K3 | c.918A>G p.R306= | Silent (SNP) | VAF 181/397 reads (46%) | catalogued as COSV67350234; called by muse, mutect2, varscan2
- PTGS2 | c.1677G>A p.K559= | Silent (SNP) | VAF 90/300 reads (30%) | catalogued as rs1248354706, COSV66570246; called by muse, mutect2, varscan2
- RIN2 | c.1716G>A p.R572= (on ENST00000255006 / NM_001242581.1; = p.R523= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as rs1392248858, COSV54783862, COSV54789973; called by muse, mutect2, varscan2
- SIGLEC1 | c.5064C>G p.T1688= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as COSV99170399; called by muse, mutect2
- SLC34A2 | c.600G>T p.A200= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV101158452, COSV65943466; called by muse, mutect2
- TRIM32 | c.714C>T p.R238= | Silent (SNP) | VAF 43/91 reads (47%) | catalogued as COSV57789218; called by muse, mutect2, varscan2
- VPS13D | c.9306C>G p.P3102= | Silent (SNP) | VAF 51/179 reads (28%) | catalogued as rs1187324553, COSV50648862; called by muse, mutect2, varscan2
- KIR3DL2 | chr19:54847235 C>T | 5'Flank (SNP) | VAF 44/298 reads (15%) | called by muse, mutect2, varscan2
- PHF20L1 | c.1637-176C>A | Intron (SNP) | VAF 11/165 reads (7%) | called by muse, mutect2
